Surgical pathology report (de-identified scan), TCGA case TCGA-G9-6373, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G9-6373-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

A. PROSTATE

SPECIMEN(S):

A. PROSTATE

CGA - G9 - 6373

GROSS DESCRIPTION:

A. PROSTATE

Received fresh labeled with the patient's identification and designated "prostate" is a resected prostate gland weighing 46 g and measuring 5.5 cm from right to left, 4.2-cm from anterior to posterior, and 3.7-cm from apex to base. The capsule is smooth and intact. A fragment of detached seminal vesicle measures 2.7 x 2.1 x 0.3 cm and detached vas deferens, 3.7-cm in length by 0.3-cm in diameter. Ink code: Apex-red, anterior-orange, posterior-black, base- blue, right-green, left-yellow. The apex and base are removed from the specimen yielding a new weight of 21 g. The specimen is serially sectioned from apex to base revealing beige tan fibrous parenchyma. The left attached seminal vesicle, 3.7 x 1.9 x 0.4 cm, and detached fragment of seminal vesicle, are bisected to show beige tan cystic tissue. A portion of the specimen is submitted for tissue procurement, the remainder entirely submitted:

A1-A2: Right apex

A3-A4: Left Apex

A5: Level 1 right anterior

A6: Level 1 right posterior

A7: Level 1 left anterior

A8: Level 1 left posterior

A9: Level 2 capsule right side

A10: Level 2 capsule left side

A11-A12: Right lateral base

A13-A15: Right base

A16: Right base with proximal urethral margin

A17: Left base with proximal urethral margin

A18-A21: Left base

A22-A23: Left lateral base

A24: Representative section, left seminal vesicle

A25: Representative sections detached seminal vesicle and detached vas

DIAGNOSIS:

A. PROSTATE, PROSTATECTOMY:

- PROSTATIC ADENOCARCINOMA, GLEASON'S GRADE 4 + 3 (SCORE 7/10), INVOLVING BOTH RIGHT AND LEFT LOBES AND AN ESTIMATED 5% OF TOTAL PROSTATE.
- EXTRACAPSULAR EXTENSION IDENTIFIED AT THE RIGHT BASE
- INKED MARGINS ARE NEGATIVE FOR TUMOR
- INFLAMMED HYPERPLASTIC UROTHELIAL MUCOSA
- SEE SYNOPTIC REPORT.

SYNOPTIC REPORT - PROSTATE GLAND

Specimens Involved

Specimens: A: PROSTATE

Location: Left

Right

Apical

Basal

WHO CLASSIFICATION

Epithelial tumors

Adenocarcinoma 8140/3

Multicentricity: Yes

Gland Involvement: 5%

Gleason Grade/Sum:: Grade 4 + 3 , Sum 7

High Grade PIN Present: Yes

Perineural Invasion: Yes

Vascular/Lymphatic Invasion: No

Seminal Vesicle Invasion: No

Periprostatic Fat Involved: Yes

[page 2 of 2]
Details: Tumor involving the periprostatic fat of right base
Bladder Neck Involved: No
Margins Involvement: No
Frozen Performed: No
Lymph Nodes: No lymph nodes sampled
Other Pathologic Findings: None identified
Pathological Staging (pTNM): T 3a N x M x
Pathological staging is based on the AJCC Cancer Staging Manual, 7th Edition
pMX: Cannot be assessed
%

CLINICAL HISTORY:

None given

PRE-OPERATIVE DIAGNOSIS:

Carcinoma, prostate

Source: NCI Genomic Data Commons file 9e3bd8cf-d85d-4843-be90-a2652b5504e9 (TCGA-G9-6373.ED631FB0-95E4-4B30-963F-1FF4CB4F0ECE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).